Surgical pathology report (de-identified scan), TCGA case TCGA-78-8662, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-8662-01A (Primary Tumor).

[page 1 of 2]
RIGHT UPPER LOBE AND LYMPH NODES

Clinical Notes:

Right upper lobe mass.

year old female.

Previous bronchitis cough and smoker 20 per day.

Four specimens are received:

1: RIGHT UPPER LOBE

Macroscopy:

Specimen is labelled "right upper lobe" and consists of a lobectomy measuring 150 x 130 x 45 mm when inflated. There is a suture line present; the sutures are removed and the resection margin inked with black ink. The pleural surface is largely smooth but is puckered in a small area in the upper medial aspect. On sectioning through the lung parenchyma deep to this region of pleural puckering there is a firm cream nodule present which measures 27 mm in maximum dimension. The nodule appears to extend to within 1 mm of the pleural surface macroscopically. The lesion is well clear of the lateral pleural aspect and of the bronchial resection margin. The lung parenchyma otherwise shows emphysema, predominantly towards the apical portion of the lung but no other lesion is identified. [RS through bronchovascular resection margin, 1A; hilar lymph nodes, 1B; tumour with medial pleural surface, 1C-1E; tumour with lateral pleural surface, 1F; random section through apical portion of lobe, 1G; random section through lower portion of lobe, 1H].

Microscopy:

Sections show a moderately to poorly differentiated adenocarcinoma with a central fibroelastotic scar. It is clear of the bronchial resection margin. The visceral pleura on the medial aspect is invaded by tumour and there is apparently focal involvement of the surface by tumour. The tumour is well clear of the lateral pleural surface. No lymphatic, vascular or perineural invasion is identified. The hilar lymph nodes and an intrapulmonary lymph node show no evidence of malignancy. The adjacent lung tissue shows features of emphysema. A tumourlet is present in the wall of a bronchus.

2: NUMBER 3 LYMPH NODE

Macroscopy:

Specimen is labelled "number 3 lymph node" and consists of a single portion of fibrofatty tissue measuring 15 x 6 x 4 mm. [BIT, 2A].

3: NUMBER 4 LYMPH NODE

[page 2 of 2]
4: NUMBER 10 LYMPH NODE

Macroscopy:

Specimen is labelled "number 10 lymph node" and consists of single piece of tan solid tissue measuring 11 x 10 x 8 mm. [Bisected and BIT, 4A] [REDACTED]

Microscopy-Specimens 2-4:

These lymph nodes show no evidence of malignancy.

Summary:

Right upper lobectomy:

- 1: Moderately to poorly differentiated adenocarcinoma, 27 mm in maximal dimension.
- 2: Visceral pleural invasion.
- 3: No vascular invasion.
- 4: No lymph node metastases.
- 5: Pathological stage T2N0MX.
-
-
-

Source: NCI Genomic Data Commons file 32ca54c3-aa1a-40d4-89ae-81065b600c9b (TCGA-78-8662.FB1023D3-D221-4DBB-80F9-0C3DD7B0750F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).